Somatic mutation profile of tumor specimen C3L-03271-01 (aliquot CPT0225190007) from CPTAC case C3L-03271, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 70.7 years (25,833 days).
Specimen C3L-03271-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e46a29e-6ebf-40ca-840b-95daf838a26c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03271-31 (Blood Derived Normal), aliquot CPT0226040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd95d64f-ac88-4324-8081-901f3bbc24b8

The open-access MAF lists 40 somatic variants for this specimen: 25 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 13, Intron 1, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+2T>C p.X1010_splice | Splice Site (SNP) | VAF 43/228 reads (19%) | hotspot (GDC flag); catalogued as COSV100577355, COSV59257966, COSV59268376, COSV59269013; called by muse, mutect2, varscan2
- CCT2 | c.144+5G>A | Splice Region (SNP) | VAF 22/204 reads (11%) | catalogued as COSV100167568; called by muse, mutect2, varscan2
- EFCAB11 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.551); catalogued as COSV99965636; called by muse, mutect2
- FAM133A | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs200416597, COSV59073455, COSV59074803; called by muse, mutect2, varscan2
- FLG | c.6788C>T p.A2263V | Missense Mutation (SNP) | VAF 31/475 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs373335399; called by muse, mutect2
- HHIPL2 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 38/459 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs776614681; called by muse, mutect2
- KIAA1586 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs974579021; called by muse, mutect2, varscan2
- MAGEC3 | c.346A>T p.R116W | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1159871208; called by muse, mutect2
- MUC4 | c.11752A>G p.T3918A | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.224); catalogued as rs1156232428, COSV57787697; called by muse, varscan2
- OR4D11 | c.839C>G p.P280R | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760658266; called by muse, mutect2
- ANK2 | c.9260C>T p.T3087I | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BTBD6 | c.1260C>A p.H420Q | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by muse, mutect2
- CCT2 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.089); called by muse, varscan2
- DCDC1 | c.4006A>G p.K1336E (on ENST00000597505 / NM_001367979.1; = p.K443E on NM_020869.3) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); called by muse, mutect2
- EARS2 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 45/487 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- FGFR4 | c.2324G>A p.C775Y | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIAA1549 | c.2333A>C p.D778A | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LAMA2 | c.7861G>A p.G2621R | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- MRGPRD | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- NYNRIN | c.4820C>T p.P1607L | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PHF8 | c.1240A>C p.I414L (on ENST00000357988 / NM_001184896.1; = p.I378L on NM_015107.3) | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIEZO2 | c.3436C>T p.H1146Y | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PTGFRN | c.2527A>G p.I843V | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- QSOX1 | c.1235A>T p.H412L | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SCN11A | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- AKR1C2 | c.639G>T p.L213= | Silent (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.612G>A p.L204= | Silent (SNP) | VAF 18/265 reads (7%) | called by muse, mutect2
- CUL1 | c.72C>T p.L24= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as COSV57393079; called by muse, mutect2, varscan2
- EFNB2 | c.633C>T p.N211= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- FMR1 | c.930G>A p.K310= | Silent (SNP) | VAF 15/242 reads (6%) | called by muse, mutect2
- GPR42 | c.495C>A p.T165= | Silent (SNP) | VAF 47/329 reads (14%) | called by muse, mutect2, varscan2
- GRAP2 | c.807G>T p.A269= | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as rs778446781; called by muse, mutect2, varscan2
- NYNRIN | c.4599C>G p.V1533= | Silent (SNP) | VAF 9/242 reads (4%) | called by muse, mutect2
- PEX26 | c.489C>T p.H163= | Silent (SNP) | VAF 35/482 reads (7%) | catalogued as rs549426563, COSV100299055; called by muse, mutect2
- PKM | c.678C>A p.I226= | Silent (SNP) | VAF 44/457 reads (10%) | called by muse, mutect2
- RLN1 | c.507G>A p.E169= | Silent (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- SLC9A3 | c.1749C>T p.V583= | Silent (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2
- STXBP6 | c.480C>T p.D160= | Silent (SNP) | VAF 22/221 reads (10%) | catalogued as rs774077268; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851230 T>A | 5'Flank (SNP) | VAF 21/394 reads (5%) | catalogued as rs545709856; called by muse, mutect2
- MYO7B | c.6250-93C>T | Intron (SNP) | VAF 10/88 reads (11%) | catalogued as rs1243970178; called by muse, mutect2, varscan2
